Somatic mutation profile of tumor specimen TCGA-55-A48Y-01A (aliquot TCGA-55-A48Y-01A-11D-A24D-08) from TCGA case TCGA-55-A48Y, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.5 years (25,384 days).
Specimen TCGA-55-A48Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a97bc7f2-55c5-44b8-b615-796c5e35b2a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-A48Y-10A (Blood Derived Normal), aliquot TCGA-55-A48Y-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad79d2d6-8895-4d5a-9293-bd019d9ceed2

The open-access MAF lists 373 somatic variants for this specimen: 291 protein-altering or splice-affecting, 73 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 257, Silent 73, Nonsense Mutation 21, Splice Site 7, Intron 6, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 1, 3'Flank 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553488015, COSV67960750, COSV67961406; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6185A>G p.Y2062C (on ENST00000272895 / NM_173076.3; = p.Y1744C on NM_015657.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs769761118, COSV55980743; called by muse, mutect2, varscan2
- ACTR3B | c.570C>G p.I190M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV55453217; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2247G>C p.Q749H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV101001952; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2918G>T p.R973L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV55004061, COSV99647551; called by muse, mutect2, varscan2
- ADARB1 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 13/189 reads (7%) | catalogued as COSV100653947, COSV62346400; called by muse, mutect2
- ADCY3 | c.3132G>A p.M1044I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761612616, COSV99568552; called by muse, mutect2, varscan2
- ADGRB2 | c.2646-1G>C p.X882_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99926510; called by muse, mutect2, varscan2
- AKAP9 | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.23); catalogued as COSV100662580; called by muse, mutect2, varscan2
- AMPH | c.494G>C p.R165P | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100342680, COSV100343083; called by muse, mutect2, varscan2
- ANKRD16 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99510468; called by muse, mutect2
- ANO7 | c.800C>T p.P267L (on ENST00000274979; = p.P213L on NM_001370694.2) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs764530986, COSV51474458, COSV99238828; called by muse, varscan2
- ANXA1 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99973981; called by muse, mutect2, varscan2
- ARHGAP17 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99253659; called by muse, mutect2, varscan2
- ARSL | c.784A>T p.T262S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV101140638; called by muse, mutect2, varscan2
- ASPN | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100978637, COSV99061785; called by muse, mutect2, varscan2
- ATF7IP2 | c.1518G>C p.L506F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV61093109; called by muse, mutect2, varscan2
- ATP1A3 | c.2328G>C p.K776N (on ENST00000545399 / NM_001256214.2; = p.K763N on NM_152296.5) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100132363; called by muse, mutect2, varscan2
- ATP8B2 | c.1240G>A p.E414K (on ENST00000672630; = p.E381K on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769350295, COSV100528090; called by muse, mutect2, varscan2
- ATXN2L | c.2403G>A p.M801I | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV100294653; called by muse, mutect2
- BACE1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100475171; called by muse, mutect2, varscan2
- BANK1 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV59846970; called by muse, mutect2, varscan2
- BAX | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53172090; called by muse, mutect2, varscan2
- BAZ1B | c.3215G>C p.G1072A | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100289888; called by muse, mutect2, varscan2
- BBX | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.364); catalogued as COSV100361849; called by muse, mutect2, varscan2
- BOD1L1 | c.4057G>C p.D1353H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV99239761; called by muse, mutect2, varscan2
- BRCA2 | c.7171G>A p.E2391K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV66450531; called by muse, mutect2, varscan2
- BSN | c.2458G>C p.E820Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV99608942; called by muse, varscan2
- BSN | c.3322G>C p.E1108Q | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99608947; called by muse, mutect2, varscan2
- BTBD6 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs587694532, COSV59270881; called by muse, mutect2
- BUB3 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV64363464; called by muse, mutect2
- C19orf57 | c.15G>C p.K5N | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100528560; called by muse, mutect2, varscan2
- C1orf56 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV99764704; called by muse, mutect2, varscan2
- CABS1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs953162881, COSV99909103; called by muse, mutect2, varscan2
- CALCOCO1 | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | catalogued as rs1267227310, COSV50416408; called by muse, mutect2
- CAMK2B | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV51662756; called by muse, mutect2, varscan2
- CAMSAP2 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.289); catalogued as COSV99373629; called by muse, mutect2, varscan2
- CARM1 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100499030; called by muse, mutect2, varscan2
- CARMIL2 | c.2348C>A p.P783Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1382162385; called by muse, varscan2
- CASP4 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1169194520, COSV101274161; called by muse, mutect2, varscan2
- CCDC83 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.301); catalogued as COSV99721799; called by muse, mutect2, varscan2
- CCDC88A | c.5437G>A p.E1813K (on ENST00000436346 / NM_001365480.1; = p.E1785K on NM_018084.5) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.647); catalogued as rs749349350, COSV99710696; called by muse, mutect2, varscan2
- CCDC9B | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1452104136, COSV101233531; called by muse, mutect2, varscan2
- CD22 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.217); catalogued as COSV99322908; called by muse, mutect2, varscan2
- CDC14A | c.387C>G p.F129L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100325386, COSV60564307; called by muse, mutect2
- CDC42BPB | c.4684G>C p.E1562Q | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV100775505, COSV63474890; called by muse, mutect2
- CELSR3 | c.2729C>T p.S910L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99374002; called by muse, mutect2, varscan2
- CENPQ | c.531G>C p.Q177H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV100225796; called by muse, mutect2
- CFAP47 | c.5524G>T p.V1842L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100545677, COSV57971446; called by muse, mutect2, varscan2
- CFL2 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as COSV53311817; called by muse, mutect2, varscan2
- CHD2 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | catalogued as COSV67707652; called by muse, varscan2
- CHFR | c.1110T>A p.S370R (on ENST00000432561 / NM_001161345.1; = p.S329R on NM_018223.2) | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99905440; called by muse, mutect2
- CHL1 | c.2189T>C p.I730T (on ENST00000397491 / NM_001253387.1; = p.I746T on NM_006614.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749639093, COSV99851567; called by muse, mutect2, varscan2
- CKAP2L | c.1371G>C p.K457N | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV100198648; called by muse, mutect2, varscan2
- CLP1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100239853; called by muse, mutect2, varscan2
- CNOT10 | c.873G>C p.L291F | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV100094667; called by muse, mutect2, varscan2
- COA8 | c.477-1G>A p.X159_splice | Splice Site (SNP) | VAF 22/138 reads (16%) | catalogued as COSV99914913; called by muse, mutect2, varscan2
- COL6A1 | c.2195C>G p.S732* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100720303; called by muse, mutect2
- CPNE1 | c.739G>C p.E247Q (on ENST00000352393; = p.E252Q on NM_003915.5) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100467688; called by muse, varscan2
- CPNE8 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); catalogued as rs750867660, COSV58847510; called by mutect2, varscan2
- CRYBA4 | c.544C>G p.H182D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100697765, COSV100697828; called by muse, mutect2
- CSNK1D | c.366G>C p.K122N | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.344); catalogued as COSV99484652; called by muse, mutect2
- CTNNB1 | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV100846286; called by muse, mutect2, varscan2
- CTNNBL1 | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100799601; called by muse, mutect2, varscan2
- CTNND2 | c.3592G>A p.V1198I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as rs1397200088, COSV100478351; called by muse, mutect2, varscan2
- DCAF12 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100778383; called by muse, mutect2, varscan2
- DCTN1 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV100720980; called by muse, mutect2, varscan2
- DDX60L | c.4018C>G p.P1340A | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99487846; called by muse, mutect2
- DEAF1 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100102157; called by muse, mutect2, varscan2
- DIABLO | c.85G>A p.E29K (on ENST00000443649 / NM_001278303.1; = p.E102K on NM_019887.6) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99928260; called by muse, mutect2, varscan2
- DIP2C | c.2075C>T p.S692L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs760322495, COSV55165121; called by muse, mutect2, varscan2
- DLST | c.1250A>T p.Y417F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV99472036; called by muse, mutect2, varscan2
- DNAH1 | c.4527G>C p.E1509D | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV101326343; called by muse, mutect2, varscan2
- DNAJC13 | c.5450C>G p.S1817C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as rs267599613, COSV99607577; called by muse, mutect2
- DOCK1 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99730759; called by muse, mutect2, varscan2
- DOCK8 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101210313; called by muse, mutect2, varscan2
- DTNB | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99977569; called by muse, mutect2, varscan2
- DYRK4 | c.777G>C p.Q259H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV50540386, COSV50540597; called by muse, mutect2
- EIF3D | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs911007896, COSV99341623; called by muse, mutect2, varscan2
- EIF3K | c.558G>C p.Q186H | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.157); catalogued as COSV99943100; called by muse, mutect2, varscan2
- EIF4A2 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as COSV100125562, COSV60624891; called by muse, mutect2, varscan2
- EPHA3 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1397249221, COSV100346435, COSV60716089; called by muse, mutect2, varscan2
- EYA3 | c.245C>G p.S82* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100870261, COSV65817343; called by muse, mutect2
- FAM126A | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as COSV101327190; called by muse, mutect2, varscan2
- FANCI | c.3352G>C p.E1118Q (on ENST00000310775 / NM_001376911.1; = p.E1058Q on NM_018193.3) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.452); catalogued as COSV100168207; called by muse, mutect2, varscan2
- FAT1 | c.3370G>C p.E1124Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as COSV71671984, COSV71676604; called by muse, mutect2, varscan2
- FBN2 | c.2590G>A p.G864R | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99328665; called by muse, mutect2
- FBXO16 | c.741-1G>A p.X247_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100672388; called by muse, mutect2
- FBXO43 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754860127, COSV101413852, COSV71054139, COSV71055382; called by muse, mutect2, varscan2
- FLG2 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs1343765274, COSV101165979; called by muse, mutect2, varscan2
- FMO4 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100882084; called by muse, mutect2, varscan2
- FNIP2 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV100032894; called by muse, mutect2, varscan2
- FRMPD3 | c.3429G>C p.E1143D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV99346587; called by muse, mutect2, varscan2
- FRY | c.8137-1G>A p.X2713_splice | Splice Site (SNP) | VAF 8/62 reads (13%) | catalogued as COSV66579086; called by muse, mutect2, varscan2
- GAB1 | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99528508; called by muse, mutect2, varscan2
- GABPA | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV100702463, COSV61395601; called by muse, mutect2, varscan2
- GALT | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM074203, CM990631, COSV101122776; called by muse, mutect2, varscan2
- GANAB | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 13/133 reads (10%) | catalogued as COSV100648105; called by muse, mutect2
- GBF1 | c.4747G>A p.A1583T (on ENST00000369983 / NM_001377137.1; = p.A1582T on NM_004193.3) | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs765179396, COSV100890551; called by muse, mutect2, varscan2
- GBP3 | c.876G>C p.E292D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as COSV99352629; called by muse, mutect2, varscan2
- GMPR | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52471868; called by muse, mutect2, varscan2
- GOLM2 | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.994); catalogued as COSV100247894; called by muse, mutect2, varscan2
- GPAA1 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV100284112; called by muse, mutect2, varscan2
- GRB2 | c.429C>A p.N143K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100353509; called by muse, mutect2, varscan2
- GRHL2 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV99307269; called by muse, mutect2, varscan2
- HAPLN4 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52269827; called by muse, mutect2, varscan2
- HEPH | c.2821G>T p.A941S (on ENST00000343002; = p.A674S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV100295129; called by muse, mutect2, varscan2
- HERC2 | c.3022C>G p.L1008V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55330895; called by muse, mutect2, varscan2
- HES2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100913943, COSV100913969; called by muse, mutect2
- HIVEP3 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56008942, COSV56015494; called by muse, mutect2, varscan2
- HIVEP3 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56013494; called by muse, mutect2, varscan2
- HNRNPUL2 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs780214569, COSV99584700; called by muse, mutect2
- HOXA3 | c.1070C>G p.T357S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV100415537, COSV100415645; called by muse, mutect2
- HSPA14 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV101000682; called by muse, mutect2, varscan2
- ICAM5 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55748704, COSV99703318, COSV99703420; called by muse, mutect2, varscan2
- IFT140 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as rs200208525, COSV101276493; called by muse, mutect2
- INHBA | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54220629, COSV54222462; called by muse, mutect2, varscan2
- IQCB1 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100181958, COSV60437555; called by muse, mutect2, varscan2
- IQCG | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99502471; called by muse, varscan2
- ISL2 | c.796-1G>A p.X266_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99320752; called by muse, mutect2, varscan2
- ITPK1 | c.888C>G p.I296M | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV99968669; called by muse, mutect2
- KATNAL2 | c.1128G>A p.M376I (on ENST00000356157 / NM_001353899.1; = p.M304I on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99797085; called by muse, mutect2, varscan2
- KCNA5 | c.624G>C p.E208D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV99363992; called by muse, mutect2, varscan2
- KIF1B | c.1035G>A p.L345= (on ENST00000377086 / NM_001365952.1; = p.L339= on NM_015074.3) | Splice Region (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99823673; called by muse, mutect2
- KIF21B | c.2631C>G p.I877M | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.212); catalogued as COSV59762660; called by muse, mutect2
- KIF26B | c.5992G>C p.E1998Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100832792; called by muse, mutect2, varscan2
- KIF5A | c.544G>C p.D182H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV99673192; called by muse, mutect2, varscan2
- KLHL22 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.362); catalogued as COSV100186125; called by muse, mutect2, varscan2
- LIMCH1 | c.1862C>G p.S621C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV100574001; called by muse, mutect2
- LPIN2 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99858553; called by muse, mutect2, varscan2
- LZTR1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV53151927; called by muse, mutect2, varscan2
- MAML3 | c.1725G>A p.M575I | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100505250; called by muse, mutect2
- MCRS1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV57791873, COSV99235423; called by muse, mutect2
- METTL27 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as COSV99936529; called by muse, mutect2
- MGAT4C | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV100153085, COSV59831210; called by muse, mutect2, varscan2
- MICAL3 | c.5027C>T p.P1676L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.122); catalogued as rs761715830, COSV101490918; called by muse, mutect2, varscan2
- MMADHC | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.721); catalogued as rs756908515, COSV100307255; called by muse, mutect2
- MMEL1 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV99984017; called by muse, mutect2, varscan2
- MMP9 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV100812404; called by muse, mutect2, varscan2
- MNDA | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751266784, COSV63740840; called by mutect2, varscan2
- MPZ | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs573007540, CM013585, COSV60668081; ClinVar: likely benign; called by muse, mutect2, varscan2
- MRPS2 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99613522; called by muse, mutect2, varscan2
- MYLPF | c.12G>C p.K4N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100363114; called by muse, mutect2, varscan2
- MYO1D | c.612C>G p.F204L | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV100554543; called by muse, mutect2, varscan2
- NANS | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs774179344, COSV99271298; called by muse, mutect2
- NCF2 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.853); catalogued as rs750380443, COSV100838911; called by muse, mutect2, varscan2
- NCKIPSD | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs753095788, COSV99584054; called by muse, mutect2, varscan2
- NCKIPSD | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1472017902, COSV99584060; called by muse, mutect2, varscan2
- NCOA3 | c.2365A>G p.T789A | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100507761; called by muse, mutect2, varscan2
- NDC80 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV55246733, COSV99859755; called by muse, mutect2, varscan2
- NFE2L3 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV99283829; called by muse, mutect2, varscan2
- NIN | c.4006C>T p.Q1336* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV55384665; called by muse, mutect2
- NIPBL | c.3310A>G p.R1104G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as COSV99241205; called by mutect2, varscan2
- NLRC5 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV99347660; called by muse, mutect2
- NMT1 | c.1266C>G p.F422L | Missense Mutation (SNP) | VAF 60/280 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); catalogued as COSV99364865; called by muse, mutect2, varscan2
- NPDC1 | c.153G>C p.K51N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV100858761; called by muse, mutect2, varscan2
- NPTN | c.133G>C p.G45R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99766324; called by muse, mutect2
- NR0B2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs75738889, CM104548; called by muse, mutect2, varscan2
- NRP1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1448051089, COSV99589045; called by muse, mutect2
- NTHL1 | c.886C>T p.R296C (on ENST00000219066; = p.R288C on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs571813695, COSV99526388; called by muse, mutect2, varscan2
- OGG1 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV99844824; called by muse, mutect2, varscan2
- OR2W3 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs750858075, COSV64455944, COSV64458463; called by muse, mutect2, varscan2
- OR4A15 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.067); catalogued as COSV59035140; called by muse, mutect2, varscan2
- OR4A16 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV59042828, COSV59044257; called by muse, mutect2
- OR5C1 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as COSV101030582; called by muse, mutect2
- OR5C1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.644); catalogued as COSV101030584; called by muse, mutect2
- OR9K2 | c.422C>T p.A141V (on ENST00000305377; = p.A119V on NM_001005243.1) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs138102893, COSV59531898; called by muse, mutect2, varscan2
- PARN | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100421105; called by muse, mutect2, varscan2
- PCF11 | c.4628C>T p.S1543F | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs1048161156, COSV100018689; called by muse, mutect2
- PCLO | c.3833G>T p.G1278V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV100434150, COSV99067602; called by muse, mutect2, varscan2
- PCSK7 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100309430; called by muse, mutect2, varscan2
- PCSK7 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100309431; called by muse, mutect2, varscan2
- PCSK7 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); catalogued as COSV100309432, COSV56121011; called by muse, mutect2, varscan2
- PDHA2 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV54782928, COSV99757312; called by muse, mutect2, varscan2
- PDPR | c.1876C>G p.L626V | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.028); catalogued as rs368469864; called by muse, mutect2, varscan2
- PDXK | c.615G>C p.Q205H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.02); catalogued as COSV99376532; called by muse, mutect2, varscan2
- PLG | c.2213G>A p.R738K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV100369351; called by muse, mutect2, varscan2
- PNPO | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as COSV99846527; called by muse, mutect2
- POLDIP2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99134823; called by muse, mutect2
- POM121C | c.894G>T p.K298N (on ENST00000607367; = p.K56N on NM_001099415.3) | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99992838; called by muse, mutect2, varscan2
- PPP1R15B | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV65815382; called by muse, mutect2
- PPRC1 | c.4018G>A p.A1340T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99531791; called by muse, mutect2, varscan2
- PRUNE2 | c.3913G>C p.E1305Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV100944357; called by muse, mutect2, varscan2
- PTCD3 | c.1633C>T p.Q545* | Nonsense Mutation (SNP) | VAF 7/103 reads (7%) | catalogued as COSV99606074; called by muse, mutect2
- PWP1 | c.132-1G>A p.X44_splice | Splice Site (SNP) | VAF 4/63 reads (6%) | catalogued as rs1187174493, COSV101338836; called by muse, mutect2
- RCN3 | c.138T>A p.D46E | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV99571371; called by muse, mutect2, varscan2
- REN | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV99689600; called by muse, varscan2
- RIF1 | c.3023C>T p.S1008L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99690782; called by muse, mutect2
- ROR1 | c.2187G>C p.W729C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935366; called by muse, mutect2, varscan2
- RPS15 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV51836603, COSV99245352; called by muse, mutect2, varscan2
- RREB1 | c.1567A>T p.T523S | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100619840; called by muse, mutect2, varscan2
- RYR3 | c.11237A>C p.N3746T (on ENST00000389232; = p.N3747T on NM_001036.6) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101213133; called by muse, mutect2, varscan2
- SCMH1 | c.725C>G p.P242R (on ENST00000326197 / NM_001031694.2; = p.P195R on NM_012236.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as COSV100401920; called by muse, mutect2, varscan2
- SDC3 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs745905618, COSV100232347; called by muse, mutect2, varscan2
- SDHD | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99736295; called by muse, mutect2, varscan2
- SEC24B | c.1764C>G p.F588L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99493810; called by muse, mutect2
- SELENOS | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV101237234; called by muse, mutect2
- SEPHS1 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV100525920; called by muse, mutect2, varscan2
- SERINC5 | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101549103; called by muse, mutect2
- SERPINB2 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100208523; called by muse, mutect2
- SERTAD2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1184764516, COSV57640211; called by muse, mutect2
- SF3B3 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100210020, COSV100210067; called by muse, mutect2, varscan2
- SLC2A4RG | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99829384; called by muse, mutect2
- SLC35G2 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1262769627, COSV101262051; called by muse, mutect2, varscan2
- SLC38A4 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775214035, COSV99872864; called by muse, mutect2, varscan2
- SLC7A4 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as rs201830341, COSV100298767; called by muse, mutect2
- SLCO1C1 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV99859402; called by muse, mutect2, varscan2
- SMARCA1 | c.1508C>G p.S503* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100946615; called by muse, mutect2, varscan2
- SMARCA4 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs371045201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA4 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60785665; called by muse, mutect2
- SNTG2 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100423384; called by muse, mutect2
- SP140 | c.2539G>C p.E847Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100613885; called by muse, mutect2, varscan2
- SPATA4 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as rs1054506456, COSV99709034; called by muse, mutect2, varscan2
- SPHKAP | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100764259, COSV60878584; called by muse, mutect2
- SPI1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.21); catalogued as rs1436543048, COSV57047541, COSV99908638; called by muse, mutect2, varscan2
- SPON1 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.91); catalogued as COSV100116179; called by muse, mutect2, varscan2
- STAG1 | c.3102G>A p.M1034I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99366004; called by mutect2, varscan2
- STAG1 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV99366009; called by muse, mutect2, varscan2
- STAG3 | c.3614C>A p.S1205Y | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as rs749884932, COSV100116819; called by muse, mutect2, varscan2
- STIL | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99681095; called by muse, varscan2
- SYT4 | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99674029; called by muse, mutect2, varscan2
- TACC1 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs754235063, COSV99393624; called by muse, mutect2, varscan2
- TBC1D4 | c.3709C>T p.L1237F | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100884661; called by muse, mutect2, varscan2
- TBC1D4 | c.2135C>G p.S712C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV100884662; called by mutect2, varscan2
- TBX21 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs1273666624, COSV51594970; called by muse, mutect2
- TCF4 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100610448; called by muse, mutect2, varscan2
- TCFL5 | c.1173G>C p.Q391H | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV53895945, COSV99415839; called by muse, mutect2, varscan2
- TCTN2 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV100315280; called by muse, mutect2, varscan2
- TEX11 | c.2077G>C p.E693Q (on ENST00000344304; = p.E678Q on NM_031276.3) | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV100721934, COSV60228555; called by muse, mutect2, varscan2
- TGM5 | c.1021G>A p.E341K (on ENST00000220420 / NM_201631.4; = p.E259K on NM_004245.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99589097; called by muse, varscan2
- TJP2 | c.2192G>C p.R731T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55270666; called by muse, mutect2
- TLR1 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV100458588; called by mutect2, varscan2
- TM9SF2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.213); catalogued as COSV100899725; called by muse, mutect2, varscan2
- TMCC2 | c.1900G>A p.V634M | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs900445841, COSV58006853; called by muse, varscan2
- TMPRSS11A | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV100602746; called by muse, mutect2, varscan2
- TMX3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as COSV100218393, COSV100218517; called by muse, mutect2, varscan2
- TNFRSF9 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1218505675, COSV101097312; called by muse, mutect2, varscan2
- TRAPPC9 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV101227904; called by muse, mutect2, varscan2
- TRIM60 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100594055; called by muse, mutect2, varscan2
- TRIM71 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV101070458; called by mutect2, varscan2
- TSR1 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.198); catalogued as COSV100027104, COSV56787342; called by muse, mutect2
- TSTD2 | c.58T>A p.F20I | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100359104; called by muse, mutect2, varscan2
- TTC7B | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100128135; called by muse, mutect2, varscan2
- TTI1 | c.1464G>C p.L488F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65063695; called by muse, mutect2, varscan2
- TTN | c.100534G>A p.D33512N (on ENST00000591111; = p.D26088N on NM_003319.4) | Missense Mutation (SNP) | VAF 40/206 reads (19%) | PolyPhen probably damaging (0.998); catalogued as rs778907927, COSV60256628; called by muse, mutect2, varscan2
- TUBGCP3 | c.372A>T p.R124S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV99996997; called by muse, mutect2, varscan2
- UBE3A | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99217458; called by muse, mutect2, varscan2
- UBN2 | c.1315C>G p.Q439E | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99944149; called by muse, mutect2, varscan2
- UBR4 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100921226; called by muse, mutect2
- UGT1A1 | c.607C>A p.H203N | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100530194, COSV100530438; called by muse, mutect2, varscan2
- UMODL1 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.07); catalogued as COSV101248649; called by muse, mutect2, varscan2
- UQCC2 | c.60G>C p.E20D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.275); catalogued as COSV100952012; called by muse, mutect2, varscan2
- VWA3A | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100241048, COSV55393057; called by muse, mutect2, varscan2
- XBP1 | c.243_244del p.R81Sfs*16 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs752398154; called by pindel, varscan2
- XPR1 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.356); catalogued as COSV100851487, COSV62559986; called by muse, mutect2
- XRN2 | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as rs1195910965, COSV101018461, COSV65871809; called by muse, mutect2, varscan2
- YLPM1 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99460264; called by muse, mutect2, varscan2
- ZBTB14 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | catalogued as COSV100813474; called by muse, mutect2
- ZFR | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99416170; called by muse, mutect2, varscan2
- ZIM3 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99518090; called by muse, mutect2
- ZKSCAN2 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV100048331; called by muse, mutect2, varscan2
- ZNF106 | c.4099C>T p.P1367S | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55522043; called by muse, mutect2, varscan2
- ZNF106 | c.3851C>T p.S1284L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99782728, COSV99782779; called by muse, mutect2, varscan2
- ZNF112 | c.2209C>T p.Q737* (on ENST00000337401 / NM_001083335.2; = p.Q731* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | catalogued as COSV100495928; called by muse, mutect2
- ZNF280A | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.033); catalogued as rs1190912674, COSV100131108; called by muse, mutect2
- ZNF281 | c.1878C>G p.F626L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99664384; called by muse, mutect2, varscan2
- ZNF333 | c.1881C>A p.F627L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52886515, COSV99469331; called by muse, mutect2, varscan2
- ZNF396 | c.740G>A p.W247* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100108597, COSV100108656; called by muse, mutect2, varscan2
- ZNF462 | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); catalogued as COSV99472466; called by muse, mutect2, varscan2
- ZNF471 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57291584; called by muse, mutect2
- ZNF667 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV52633543, COSV99410645; called by muse, mutect2, varscan2
- ZNF699 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.682); catalogued as rs1311187608, COSV100426991; called by muse, mutect2, varscan2
- ZNF699 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100426993; called by muse, mutect2
- ZNF92 | c.262G>C p.E88Q (on ENST00000328747 / NM_152626.4; = p.E19Q on NM_007139.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV100165867; called by muse, mutect2
- ATF7 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- CD33 | c.842+1G>A p.X281_splice | Splice Site (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- FRMPD4 | c.3313dup p.S1105Kfs*31 | Frame Shift Ins (INS) | VAF 46/112 reads (41%) | called by mutect2, pindel, varscan2
- GOLGA6L9 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.402); called by mutect2, varscan2
- GTF2IRD1 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- INF2 | c.2759dup p.L921Pfs*59 | Frame Shift Ins (INS) | VAF 29/168 reads (17%) | called by pindel, varscan2
- LAMB4 | c.1398G>C p.L466F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.237); called by muse, mutect2
- NYNRIN | c.1470G>C p.Q490H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2
- OBSL1 | c.1770C>A p.F590L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- OR1S1 | c.589C>G p.L197V | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.721); called by muse, mutect2
- PTPRF | c.5093G>C p.S1698T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TBCD | c.1379del p.G460Afs*24 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- TBX2 | c.1952G>T p.G651V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.444); called by muse, mutect2
- TLR4 | c.1407_1420del p.L470Sfs*43 (on ENST00000355622 / NM_138554.5; = p.L430Sfs*43 on NM_003266.4) | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- TMTC3 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2
- YARS1 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.164); called by muse, mutect2
- ZNF658 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA3 | c.3429C>T p.L1143= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100068770; called by muse, mutect2, varscan2
- ACBD4 | c.402G>C p.L134= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100416228, COSV58850936; called by muse, mutect2, varscan2
- ACTB | c.147G>A p.Q49= | Silent (SNP) | VAF 13/149 reads (9%) | catalogued as COSV100079708, COSV59318740; called by muse, mutect2
- ADAMTS20 | c.12C>T p.A4= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV101239637; called by muse, mutect2, varscan2
- ADCK2 | c.282C>T p.F94= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV50782657; called by muse, mutect2
- ADGRB2 | c.2946G>A p.L982= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99926509; called by muse, mutect2, varscan2
- ALPK2 | c.6075G>A p.P2025= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs199833082, COSV64490009, COSV64492165; called by muse, mutect2
- ANO7 | c.516C>T p.L172= (on ENST00000274979; = p.L118= on NM_001370694.2) | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99238823; called by muse, varscan2
- AOPEP | c.666T>A p.T222= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99468807; called by muse, mutect2, varscan2
- APBB3 | c.612G>A p.G204= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV100021373; called by muse, mutect2, varscan2
- AQP12B | c.270C>T p.L90= (on ENST00000621682; = p.L102= on NM_001102467.2) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV68183826; called by muse, mutect2, varscan2
- ASXL1 | c.2170C>T p.L724= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV60105724; called by mutect2, varscan2
- AUTS2 | c.369G>A p.K123= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100718182, COSV61433411; called by muse, mutect2, varscan2
- C9 | c.1320G>A p.L440= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV54682235; called by muse, mutect2, varscan2
- CNGB3 | c.999A>T p.S333= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1329766798, COSV100182331; called by muse, mutect2, varscan2
- CYC1 | c.171G>A p.R57= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as rs1205674092, COSV100010493; called by muse, mutect2, varscan2
- DHRS4L2 | c.357C>T p.V119= | Silent (SNP) | VAF 64/495 reads (13%) | catalogued as COSV100632545; called by muse, mutect2, varscan2
- DNAH9 | c.5034A>T p.I1678= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV99306580; called by muse, mutect2, varscan2
- DOP1B | c.3252G>C p.L1084= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV101215563; called by muse, mutect2
- EHBP1 | c.3282G>A p.L1094= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99861256; called by muse, mutect2, varscan2
- FMN1 | c.2418G>A p.Q806= (on ENST00000616417 / NM_001277313.2; = p.Q583= on NM_001103184.4) | Silent (SNP) | VAF 54/338 reads (16%) | catalogued as COSV100568950; called by muse, mutect2, varscan2
- G6PC2 | c.885C>G p.L295= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as COSV99960816; called by muse, mutect2, varscan2
- GPR83 | c.909C>G p.L303= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV54717652, COSV99703777; called by muse, mutect2, varscan2
- GRINA | c.135C>T p.P45= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs782607968, COSV100478115; called by muse, mutect2, varscan2
- HAPLN4 | c.738C>T p.N246= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1231164364, COSV52269614; called by muse, mutect2, varscan2
- HIPK4 | c.1512C>G p.L504= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV99396802; called by muse, mutect2, varscan2
- KIAA0100 | c.4248G>C p.L1416= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- KIF13B | c.2397C>G p.L799= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101568710; called by muse, mutect2, varscan2
- KRT31 | c.235C>A p.R79= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV99289872; called by muse, mutect2, varscan2
- LFNG | c.909G>C p.V303= (on ENST00000222725 / NM_001040167.2; = p.V174= on NM_002304.2) | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- LRFN3 | c.750C>T p.P250= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV55817213, COSV99873441; called by muse, mutect2, varscan2
- LRP1 | c.2295C>G p.V765= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV99676365; called by muse, mutect2, varscan2
- LRRC4B | c.1734C>T p.I578= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs11552705, COSV100975972; called by muse, mutect2, varscan2
- MARCHF11 | c.789C>T p.L263= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100198065; called by muse, mutect2
- METTL27 | c.174C>T p.L58= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1554636364, COSV99936531; called by muse, mutect2
- MFSD13A | c.939C>A p.V313= | Silent (SNP) | VAF 39/193 reads (20%) | catalogued as COSV99487948; called by muse, mutect2, varscan2
- MRPL37 | c.757C>T p.L253= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100289303; called by muse, mutect2, varscan2
- MYG1 | c.234G>A p.R78= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99670459; called by muse, mutect2
- MYH1 | c.4773G>A p.K1591= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as rs772448178, COSV99876299; called by muse, mutect2, varscan2
- NADSYN1 | c.1374C>T p.F458= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV100034867; called by muse, mutect2, varscan2
- NBPF11 | c.627C>T p.I209= | Silent (SNP) | VAF 28/259 reads (11%) | called by muse, mutect2, varscan2
- NID1 | c.2007G>A p.Q669= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99937745; called by muse, mutect2
- OR10H2 | c.903C>G p.A301= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV100008810, COSV59945883; called by muse, mutect2
- OR6T1 | c.906A>G p.R302= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as COSV100190047; called by muse, mutect2, varscan2
- OR7G1 | c.483G>A p.L161= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV53318425, COSV99528649; called by muse, mutect2, varscan2
- PCDH17 | c.1893C>T p.N631= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV64971878; called by muse, mutect2
- PDE6B | c.2046C>T p.I682= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs774172884, COSV55328623; called by muse, mutect2, varscan2
- PLCD3 | c.1593G>A p.L531= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100504299; called by muse, mutect2
- PNPLA7 | c.1338G>A p.R446= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV99481016; called by muse, mutect2
- PREX2 | c.1272G>A p.E424= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV99908190; called by muse, mutect2, varscan2
- PTH2R | c.385C>T p.L129= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV99782637; called by muse, mutect2, varscan2
- QRICH2 | c.3318G>A p.R1106= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV99429414; called by muse, mutect2, varscan2
- RAB3D | c.522G>A p.Q174= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV99708904; called by muse, mutect2, varscan2
- RBM25 | c.774C>G p.L258= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV99998831; called by muse, mutect2, varscan2
- RDH8 | c.753G>C p.V251= (on ENST00000651512; = p.V231= on NM_015725.4) | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV99408716; called by muse, mutect2, varscan2
- SIPA1L2 | c.3024C>T p.I1008= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99478819; called by muse, varscan2
- SLC6A4 | c.1362C>T p.F454= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs759630152, COSV55566986; called by muse, mutect2, varscan2
- SMARCA1 | c.1611G>A p.P537= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs775439088, COSV64412534; called by muse, varscan2
- SSH1 | c.2367G>A p.L789= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV100425649; called by muse, mutect2, varscan2
- SSTR3 | c.177G>T p.L59= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV100142734; called by muse, mutect2, varscan2
- STAG3 | c.924C>G p.V308= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100426048; called by muse, mutect2, varscan2
- STAG3 | c.1101G>C p.L367= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV57934502; called by muse, mutect2, varscan2
- TACR3 | c.261C>G p.L87= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as rs1262399399, COSV100510631; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4599C>T p.S1533= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs138321958; called by muse, mutect2, varscan2
- TSC2 | c.3426G>T p.L1142= | Silent (SNP) | VAF 12/214 reads (6%) | catalogued as COSV54774693; called by muse, mutect2
- UNC93A | c.1373G>A p.*458= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV100023423, COSV57808839; called by muse, mutect2
- USH2A | c.2592A>T p.S864= | Silent (SNP) | VAF 28/195 reads (14%) | catalogued as COSV100237774; called by muse, mutect2, varscan2
- VPS4A | c.567C>T p.F189= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs1392238451, COSV99652027; called by muse, mutect2, varscan2
- WDR1 | c.303C>T p.F101= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs773064561, COSV53332296; called by muse, mutect2, varscan2
- YLPM1 | c.345C>G p.L115= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99460258; called by muse, mutect2, varscan2
- ZBTB48 | c.88C>T p.L30= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100039745; called by muse, mutect2
- ZNF236 | c.4650G>C p.S1550= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV53486408, COSV99469416, COSV99470653; called by muse, mutect2, varscan2
- ZNF598 | c.888G>A p.R296= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV101461973; called by muse, mutect2, varscan2
- CCDC30 | c.385-6180C>T | Intron (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100501454; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055750 G>A | 3'Flank (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- GCNT2 | c.926-35046G>A | Intron (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99399408; called by muse, mutect2, varscan2
- LINC02870 | n.398G>A | RNA (SNP) | VAF 17/130 reads (13%) | catalogued as rs775434861; called by muse, mutect2, varscan2
- MAP4 | c.1999+5513C>T | Intron (SNP) | VAF 13/91 reads (14%) | catalogued as rs1445325850, COSV99275714; called by muse, mutect2, varscan2
- NINJ2 | c.-1G>A | 5'UTR (SNP) | VAF 25/129 reads (19%) | catalogued as rs569602741, COSV100523202; called by muse, mutect2, varscan2
- PLCE1 | c.1207-42888G>A | Intron (SNP) | VAF 25/144 reads (17%) | catalogued as COSV99595636; called by muse, mutect2, varscan2
- PXN | c.832-277C>T | Intron (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99936033; called by muse, mutect2, varscan2
- RC3H2 | c.961-171G>A | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as rs1319257624, COSV100106734; called by mutect2, varscan2
